Somatic mutation profile of tumor specimen MP2PRT-PAVTJI-TBP1-A (aliquot MP2PRT-PAVTJI-TBP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVTJI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,808 days).
Specimen MP2PRT-PAVTJI-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f376bd55-7c37-4ae3-94b0-1b1196799fb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTJI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTJI-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4de3993-eb63-436c-b1cc-c93b1ba78af1

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 28/514 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs121913627, CM1413733, CM920492, COSV62519806; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SEC24B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs764552953; called by muse, mutect2
